Surgical pathology report (de-identified scan), TCGA case TCGA-YU-A94C, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-YU-A94C-01A (Primary Tumor).

ICD-O 3

Mixed germ cell tumor
9085/3
Site O Testis NOS C62.9
gn 3/3/14

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Left testis

“Left testis”:

- Mixed germ cell tumor (seminoma [20%], embryonal carcinoma [50%], yolk sac tumor [10%], immature teratoma [10%], choriocarcinoma [10%])
- Neoplasia size: 8.0 x 5.5 x 5.0cm
- Presence of necrosis
- Angiolymphatic and perineural invasions not detected
- Absence of intratubular neoplasia
- The neoplasia infiltrates tunica albuginea and spermatic cord
- Epididymis: compromised by the neoplasia
- Rete testis: free of neoplasia
- Tunica vaginalis free of neoplasia
- Margin of spermatic cord free of neoplasia
- Adjacent parenchyma exhibiting atrophy.

PATHOLOGIC STAGING

Topography	Morphology	Stage
Testis, NOS	Mixed germ cell tumor	pT3

Criteria	hw 11/18/13	Yes	No

Source: NCI Genomic Data Commons file 4232704f-260e-4dcf-9cc3-792ee7ac5f43 (TCGA-YU-A94C-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).